Somatic mutation profile of tumor specimen MP2PRT-PARTYW-TMP1-A (aliquot MP2PRT-PARTYW-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARTYW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,493 days).
Specimen MP2PRT-PARTYW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 732ea39a-6b4a-4bd3-a02f-cab19ac34dac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTYW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTYW-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94432bea-9e3d-4e22-afb8-19fea8e72fe4

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 3, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>T p.X366_splice | Splice Site (SNP) | VAF 82/298 reads (28%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXO25 | c.188C>T p.A63V (on ENST00000382824 / NM_183421.2; = p.H13Y on NM_012173.3) | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1297779728; called by muse, mutect2, varscan2
- IDH1 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 121/427 reads (28%) | catalogued as rs912110895; called by muse, mutect2, varscan2
- LRRC74B | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs926085351; called by muse, mutect2, varscan2
- CELF2 | c.1509_1510insCC p.D504Pfs*18 (on ENST00000416382 / NM_001025077.3; = p.D517Pfs*18 on NM_006561.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 69/230 reads (30%) | called by mutect2, varscan2
- CELF2 | c.1510delinsCCC p.D504Pfs*18 (on ENST00000416382 / NM_001025077.3; = p.D517Pfs*18 on NM_006561.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 20/192 reads (10%) | called by mutect2*, pindel, varscan2*
- CTC1 | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRAXIN | c.985_991delinsCC p.R329Pfs*54 | Frame Shift Del (DEL) | VAF 150/528 reads (28%) | called by pindel, varscan2*
- FREM1 | c.3174T>A p.D1058E | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- INTS8 | c.968T>C p.L323S | Missense Mutation (SNP) | VAF 123/267 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC1 | c.1852G>T p.G618W | Missense Mutation (SNP) | VAF 225/442 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NDUFS3 | c.156T>A p.D52E | Missense Mutation (SNP) | VAF 170/669 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAET1L | c.159A>C p.Q53H | Missense Mutation (SNP) | VAF 111/555 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SAMD7 | c.1133C>A p.A378E | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SECISBP2L | c.1680dup p.G561Rfs*16 (on ENST00000559471 / NM_001193489.2; = p.G516Rfs*16 on NM_014701.4) | Frame Shift Ins (INS) | VAF 78/271 reads (29%) | called by mutect2, varscan2
- TSSK2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 91/556 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.22449G>T p.K7483N (on ENST00000591111; = p.K6556N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/345 reads (27%) | PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CENPE | c.750G>A p.V250= | Silent (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- LRRC74A | c.195G>A p.S65= | Silent (SNP) | VAF 85/306 reads (28%) | catalogued as rs1419011344; called by muse, mutect2, varscan2
- THTPA | c.639C>T p.N213= | Silent (SNP) | VAF 115/437 reads (26%) | catalogued as rs756428786; called by muse, mutect2, varscan2
